Somatic mutation profile of tumor specimen TCGA-AO-A12F-01A (aliquot TCGA-AO-A12F-01A-11D-A10Y-09) from TCGA case TCGA-AO-A12F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 36.7 years (13,409 days).
Specimen TCGA-AO-A12F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f442c0a6-9d6a-43e2-aee4-b0bce716912f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A12F-10A (Blood Derived Normal), aliquot TCGA-AO-A12F-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb43318-69c7-487e-804a-5659bea9dce0

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2B | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53196942; called by muse, mutect2, varscan2
- BICRAL | c.2690del p.T897Kfs*8 | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | catalogued as COSV58404608; called by mutect2, pindel, varscan2
- BTBD3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1288273925, COSV54778657, COSV54778921; called by muse, mutect2, varscan2
- CDX4 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs1463443044, COSV65171547; called by muse, mutect2, varscan2
- CDX4 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65171550; called by muse, mutect2, varscan2
- CEP126 | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV54823721; called by muse, mutect2, varscan2
- FAM47B | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV61453174; called by muse, mutect2, varscan2
- FLG | c.9958C>T p.R3320C | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770664817, COSV64239791; called by muse, mutect2, varscan2
- IGFN1 | c.2894C>A p.T965K (on ENST00000295591 / NM_001367841.1; = p.T3422K on NM_001164586.2) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99811434; called by muse, mutect2
- KPNA2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs782272780, COSV57857203; called by muse, mutect2, varscan2
- KRT14 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.328); catalogued as COSV51420955; called by muse, varscan2
- MKRN2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751152524, COSV50104409; called by muse, mutect2, varscan2
- MORN3 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749150906, COSV62507173; called by muse, mutect2, varscan2
- MYH1 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 109/124 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs201766006; called by muse, mutect2, varscan2
- NHLRC1 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV61481296; called by muse, mutect2, varscan2
- PLIN4 | c.484C>T p.L162F (on ENST00000301286; = p.L177F on NM_001367868.2) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV56689632; called by muse, mutect2, varscan2
- POSTN | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65712535; called by muse, mutect2, varscan2
- RGS22 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754379341, COSV62664215; called by muse, mutect2
- SEMA4A | c.2099T>A p.I700N | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100740484; called by muse, mutect2
- SESN2 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs760115188, COSV53427217; called by muse, mutect2
- TAF1 | c.2575A>G p.M859V (on ENST00000373790 / NM_138923.4; = p.M880V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/134 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs760338471, COSV52110643; called by muse, mutect2, varscan2
- TG | c.1985G>A p.C662Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55071484; called by muse, mutect2, varscan2
- TLR2 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs376311320; called by muse, mutect2
- TRIM6 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1363105687, COSV53475336; called by muse, mutect2, varscan2
- UNC13C | c.2987G>C p.S996T | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.076); catalogued as COSV52859404; called by muse, mutect2, varscan2
- UNC93A | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs549125660, COSV57807844; called by muse, mutect2, varscan2
- WRAP53 | c.1399G>C p.V467L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV56833193; called by muse, mutect2, varscan2
- ZNF320 | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67087879; called by muse, mutect2, varscan2
- ZXDC | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100306518, COSV60446542; called by muse, mutect2, varscan2
- COL14A1 | c.4542_4551+22del p.X1514_splice | Splice Site (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- DMRT2 | c.600del p.S201Vfs*8 | Frame Shift Del (DEL) | VAF 55/116 reads (47%) | called by mutect2, pindel, varscan2
- C2orf16 | c.120A>C p.G40= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV101284345; called by muse, mutect2
- CLASRP | c.1755G>C p.A585= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55515455; called by muse, mutect2, varscan2
- DUSP1 | c.1011C>T p.T337= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs763215828, COSV53319914; called by muse, mutect2, varscan2
- OPCML | c.1011C>A p.L337= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as COSV59415093, COSV59434691; called by muse, mutect2, varscan2
- PGAP2 | c.243C>T p.I81= (on ENST00000463452 / NM_001346398.2; = p.I142= on NM_014489.4) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs376399242; called by muse, mutect2
- PXDNL | c.4068G>A p.L1356= | Silent (SNP) | VAF 27/259 reads (10%) | catalogued as rs757840742, COSV100682175; called by muse, mutect2, varscan2
